Somatic mutation profile of tumor specimen TCGA-EL-A3GP-01A (aliquot TCGA-EL-A3GP-01A-11D-A202-08) from TCGA case TCGA-EL-A3GP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 70.4 years (25,696 days).
Specimen TCGA-EL-A3GP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee19746-0f5b-4c02-9285-63f83ec8dab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GP-10A (Blood Derived Normal), aliquot TCGA-EL-A3GP-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/425ce523-3f94-4402-a412-91816155a9b7

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACACB | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV58142065; called by muse, mutect2, varscan2
- AGGF1 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV57230600; called by muse, mutect2, varscan2
- ALDH1L1 | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56417465; called by muse, mutect2, varscan2
- CYTH4 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50634561; called by muse, mutect2, varscan2
- DOCK3 | c.5101G>A p.G1701S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs747786193, COSV56511170; called by muse, mutect2, varscan2
- FAAH | c.1332_1333del p.W445Gfs*70 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs1192146871; called by pindel, varscan2
- PCDH15 | c.2407C>G p.L803V | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as COSV57265675, COSV57364560; called by muse, mutect2, varscan2
- SUPT20H | c.2336T>G p.F779C | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV53508833; called by muse, mutect2, varscan2
- SYNE1 | c.3773A>G p.Q1258R (on ENST00000367255 / NM_182961.4; = p.Q1265R on NM_033071.3) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99573539; called by muse, mutect2, varscan2
- SYNE1 | c.3772C>A p.Q1258K (on ENST00000367255 / NM_182961.4; = p.Q1265K on NM_033071.3) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99573544; called by muse, mutect2, varscan2
- UBP1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV52146936; called by muse, mutect2, varscan2
- USP6 | c.4098T>A p.Y1366* | Nonsense Mutation (SNP) | VAF 49/181 reads (27%) | catalogued as COSV51491528; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1189del p.V397* | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- ASXL1 | c.2226G>C p.G742= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV60116297; called by muse, mutect2, varscan2
- CCDC54 | c.618C>T p.D206= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs779037242, COSV53759537, COSV53759685; called by muse, mutect2, varscan2
- KIAA1755 | c.1176A>G p.S392= | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as rs779486855, COSV54079232; called by muse, mutect2, varscan2
- NOS1 | c.1017C>A p.S339= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV57612798, COSV57618228; called by muse, mutect2, varscan2
- OR2T27 | c.819T>A p.A273= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV61283070; called by muse, mutect2, varscan2
- ZNF746 | c.1848C>T p.S616= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV61408466; called by muse, mutect2, varscan2
- KRT18P55 | n.1170A>G | RNA (SNP) | VAF 24/68 reads (35%) | catalogued as rs138730739; called by muse, mutect2, varscan2
